Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A4KG, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A4KG-01A (Primary Tumor).

[page 1 of 2]
Collected: _____
Received: _____ Case type: Surgical Case
DOB _____ Sex: F
Physician: _____
Accession _____

DIAGNOSIS

(A) RIGHT THYROID LOBE AND ISTHMUS PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe
Multi-focal: No
Size = 2 cm
Extrathyroidal extension: Present, extending into fibroadipose tissue
Lymphovascular invasion: Not identified
Resection Margins: Negative
Lymph nodes: No tumor present in 1 lymph node
Parathyroid tissue, negative for tumor

(B) RULE OUT PORTION OF RIGHT INFERIOR PARATHYROID GLAND Parathyroid and Thymic tissue

(C) RULE OUT PORTION RIGHT SUPERIOR PARATHYROID GLAND Hypercellular parathyroid tissue

(D) MIDLINE TISSUE, RULE OUT PARATHYROID Hypercellular parathyroid tissue

(E) LEFT THYROID LOBE Colloid nodule

ICD-O-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9
lw
10/4/12

GROSS DESCRIPTION

(A) RIGHT THYROID LOBE AND ISTHMUS – The specimen consists of a right lobe (3.5 x 3.0 x 1.5 cm) with attached isthmus 1.0 x 0.5 x 0.5 cm.
The specimen is serially sectioned from superior-to-inferior to reveal a white mass (2.0 x 1.5 x 1.0 cm) located mainly in the middle and inferior part of the right lobe.
Representative sections are submitted for tissue bank.
The specimen is submitted entirely in nine cassettes.
SECTION CODE: A1-A8, right lobe from superior to inferior (tumor from cassette #4 to cassette #8); A9, the isthmus.

(B) RULE OUT PORTION OF RIGHT INFERIOR PARATHYROID GLAND – The specimen consists of 0.2 x 0.2 x 0.1 cm tan soft tissue. The specimen is submitted entirely for frozen section diagnosis in one cassette. Touch prep is done on the specimen.

*FS/DX: parathyroid and Thymic tissue.

(C) RULE OUT PORTION RIGHT SUPERIOR PARATHYROID GLAND – The specimen consists of a 0.3 x 0.2 x 0.2 cm tan soft tissue. The specimen is submitted entirely for frozen section diagnosis in one cassette.

[page 2 of 2]
DOB:
Physician

Sex: F

Collected
Received:

Pathologist:
Case type: Surgical Case

Accession:

*FS/DX: parathyroid hyperplasia.

(D) MIDLINE TISSUE, RULE OUT PARATHYROID – The specimen is 0.3 x 0.2 x 0.1 cm tan soft tissue. The specimen is submitted entirely for frozen section diagnosis in one cassette.

*FS/DX: parathyroid hyperplasia.

(E) LEFT THYROID LOBE – A lobe of thyroid (4.3 x 3.0 x 1.4 cm) with smooth glistening capsule. Specimen is serially sectioned from superior to inferior to reveal a circumscribed pale tan, shiny, homogenous nodule (1.1 x 1.0 x 0.7 cm) that is predominantly located in the superior pole. The remaining thyroid parenchyma is red-brown and homogenous. Representative sections submitted.

SECTION CODE: Representative sections submitted in sequential order from superior to inferior with nodule located in E1 and E2.

CLINICAL HISTORY

PTC right lobe

SNOMED CODES

T-B6000, M-80503, T-C4200, M-00110, "Some tests reported here may have been developed and performance characteristics determined by se tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 2 of 2	
File under: Pathology			

Source: NCI Genomic Data Commons file 3fc95a94-6e02-4451-9ec7-5ed9e694ed07 (TCGA-EL-A4KG.8B4D292E-EF9B-4457-91EE-754DD5E112E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).